Gene-level copy-number profile of tumor specimen TCGA-RN-AAAQ-01A from TCGA case TCGA-RN-AAAQ, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of head, face, and neck; Age at diagnosis: 52.4 years (19,123 days).
Specimen TCGA-RN-AAAQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.77d2ed4f-892f-465e-a00d-65979ffaffe8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-RN-AAAQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7b3aaf27-3216-4d04-b08f-8c13256e1e65

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 137; copy number 1: 1,064; copy number 2: 18,457; copy number 3: 13,677; copy number 4: 19,637; copy number 5: 2,458; copy number 6: 1,510; copy number 7: 1,183; copy number 8: 1,151; copy number 9: 120; copy number 10: 312; copy number 11: 53; copy number 12: 50.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-RN-AAAQ-01A-21D-A38Y-01): tumor purity 0.58, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 137 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:12,098,660–15,362,134, 43 genes: AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P, CLCN3P1, LDHAP4, AL592293.1, PSIP1P1, RNU6-559P, TTC39B, RPL7P33.
- chr9:19,453,209–25,089,151, 94 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 535 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:31,400,497–43,886,628, 234 genes, copy number 10 (broad region; genes not listed).
- chr7:76,818,377–77,957,503, 30 genes, copy number 10 (within-gene range 8–10): AC006972.1, AC007003.1, DTX2P1-UPK3BP1-PMS2P11, FDPSP7, AC114737.1, DTX2P1, UPK3BP1, PMS2P11, Y_RNA, SPDYE17, PMS2P9, Y_RNA, AC007000.3, SPDYE18, AC007000.2, FAM185BP, AC007000.1, CCDC146, FGL2, AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA.
- chr7:81,946,444–82,443,777, 1 gene, copy number 12 (within-gene range 8–12): CACNA2D1.
- chr7:90,466,424–91,210,590, 1 gene, copy number 11 (within-gene range 8–11): CDK14.
- chr7:91,030,149–92,836,573, 33 genes, copy number 11 (within-gene range 8–11): AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P.
- chr7:100,706,121–102,283,958, 48 genes, copy number 10 (within-gene range 8–10): POP7, EPO, ZAN, EPHB4, RN7SL750P, SLC12A9, SLC12A9-AS1, TRIP6, MIR6875, SRRT, UFSP1, ACHE, RN7SL549P, RPS29P15, MUC3A, AC254629.1, MUC12, MUC12-AS1, MUC17, RN7SKP54, TRIM56, SERPINE1, AP1S1, MIR4653, VGF, NAT16, MOGAT3, DGAT2L7P, RPSAP46, PLOD3, ZNHIT1, CLDN15, FIS1, RNU6-1104P, AC006329.1, AZGP1P2, LNCPRESS1, EMSLR, IFT22, COL26A1, AC004965.1, LINC01007, MYL10, CUX1, AC005096.1, AC005072.1, AC005086.2, AC005086.5.
- chr7:106,125,371–108,995,029, 49 genes, copy number 12: DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1, AC005050.2, CCDC71L, LINC02577, RNA5SP236, PIK3CG, PRKAR2B, PRKAR2B-AS1, HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:156,263,547–157,269,370, 19 genes, copy number 11 (within-gene range 7–11): AC093813.1, LINC01006, LINC00244, AC005534.1, RNF32, RNF32-AS1, LMBR1, RNU4-31P, AC006357.1, NOM1, MNX1, MNX1-AS2, MNX1-AS1, AC006967.2, AC006967.1, AC006967.3, UBE3C, RPS27AP12, AC004898.1.
- chr12:66,767–991,190, 25 genes, copy number 9: IQSEC3, AC026369.3, AC026369.1, AC026369.2, AC007406.3, SLC6A12, AC007406.1, SLC6A12-AS1, SLC6A13, AC007406.2, AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1.
- chr14:103,121,476–105,398,147, 95 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,008. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
